Somatic mutation profile of tumor specimen TCGA-86-7954-01A (aliquot TCGA-86-7954-01A-11D-2184-08) from TCGA case TCGA-86-7954, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,062 days).
Specimen TCGA-86-7954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 782eaec0-34e1-4561-a190-2355811282e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7954-10A (Blood Derived Normal), aliquot TCGA-86-7954-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ff606b8-6f4d-4b67-9cbb-f3c9ac6755bc

The open-access MAF lists 225 somatic variants for this specimen: 155 protein-altering or splice-affecting, 62 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 62, Nonsense Mutation 10, RNA 5, Splice Site 3, Frame Shift Ins 2, Frame Shift Del 2, Translation Start Site 2, In Frame Ins 1, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs369673758; called by muse, mutect2, varscan2
- AKAP6 | c.1270A>T p.S424C | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55212734; called by muse, mutect2, varscan2
- ALX3 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63928754; called by muse, mutect2, varscan2
- ANKRD11 | c.709C>G p.P237A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1176951081, COSV56360320; called by muse, mutect2, varscan2
- ANKRD30A | c.2752G>T p.V918F (on ENST00000611781; = p.V862F on NM_052997.2) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100654570, COSV64625736; called by muse, mutect2
- APOB | c.6046G>T p.D2016Y | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs755811872, COSV51934180; called by muse, mutect2, varscan2
- ARMCX2 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV100168337; called by muse, mutect2, varscan2
- AWAT1 | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV100997241; called by muse, mutect2, varscan2
- BABAM2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558639513, COSV59622455, COSV59628195; called by muse, mutect2
- BCLAF3 | c.681T>G p.Y227* | Nonsense Mutation (SNP) | VAF 16/172 reads (9%) | catalogued as COSV61413806; called by muse, mutect2
- BEX2 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65500958; called by muse, mutect2
- BFAR | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as COSV55493175; called by muse, mutect2, varscan2
- BRWD3 | c.5206A>C p.M1736L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64747578; called by muse, mutect2, varscan2
- BTAF1 | c.5041A>G p.I1681V | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56433553; called by muse, mutect2, varscan2
- BTLA | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57938270; called by muse, mutect2
- CAPN6 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 58/700 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60694814; called by muse, mutect2
- CDH9 | c.2279G>A p.C760Y | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV50251711, COSV50279379; called by muse, mutect2
- CES5A | c.1700A>C p.Q567P (on ENST00000290567 / NM_001143685.2; = p.Q517P on NM_145024.3) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV51866028; called by muse, mutect2
- CFH | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs62641696, COSV66408840; called by muse, mutect2, varscan2
- CFHR5 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56821552; called by muse, mutect2, varscan2
- CNKSR2 | c.2922A>C p.K974N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV65279207; called by muse, mutect2
- CNTNAP2 | c.2324C>T p.T775I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100673928, COSV62175891; called by muse, mutect2, varscan2
- COL11A1 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62182534; called by muse, mutect2, varscan2
- COL12A1 | c.8291G>T p.R2764I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59395350; called by muse, mutect2
- COL19A1 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59571868; called by muse, mutect2, varscan2
- COL4A6 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57865551, COSV57868618; called by muse, mutect2, varscan2
- CPEB4 | c.1826A>G p.Y609C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV54171539; called by muse, mutect2, varscan2
- CPM | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58033062; called by muse, mutect2, varscan2
- CRB1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66340206, COSV66348134; called by muse, mutect2, varscan2
- CSNK1A1L | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV65789635; called by muse, mutect2, varscan2
- CYP3A5 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1414346579, COSV56119815; called by muse, mutect2
- DACH2 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs866223944, COSV100914154, COSV64167882; called by muse, mutect2, varscan2
- DDI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV56375816; called by muse, mutect2
- DMD | c.8685G>C p.E2895D | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100628693, COSV58908217; called by muse, mutect2, varscan2
- DNAH10 | c.8380G>T p.D2794Y (on ENST00000409039; = p.D2733Y on NM_207437.3) | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68993005; called by muse, mutect2, varscan2
- DRD3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as rs201876283, COSV55680023, COSV99879740; called by muse, mutect2, varscan2
- DSE | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59063668, COSV59066716; called by muse, mutect2, varscan2
- ELN | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as COSV52709908; called by muse, mutect2, varscan2
- ENOX2 | c.1259G>T p.S420I (on ENST00000338144 / NM_001382520.1; = p.S391I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57651088; called by muse, mutect2
- FAM151A | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56363980; called by muse, mutect2, varscan2
- FAM166C | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61593051, COSV61593272; called by muse, mutect2, varscan2
- FAT2 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV55819057; called by muse, mutect2
- FOXP2 | c.1761G>T p.K587N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63485582; called by muse, mutect2
- GALNT17 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV61160738; called by muse, mutect2
- GDNF | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1389990693, COSV58479328; called by muse, mutect2
- GPIHBP1 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV58209172, COSV58209585; called by muse, mutect2, varscan2
- GRIA3 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV52058192, COSV52080369; called by muse, mutect2, varscan2
- HAO1 | c.623A>T p.Y208F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV66491895; called by muse, mutect2, varscan2
- HORMAD1 | c.33+2T>G p.X11_splice | Splice Site (SNP) | VAF 17/86 reads (20%) | catalogued as COSV59271034; called by muse, mutect2, varscan2
- HOXA3 | c.1310C>A p.A437E | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57826233; called by muse, mutect2
- HSPA4 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV59182450; called by muse, mutect2, varscan2
- IFT20 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/113 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as COSV56876500; called by muse, mutect2, varscan2
- IFT57 | c.213-1G>C p.X71_splice | Splice Site (SNP) | VAF 15/102 reads (15%) | catalogued as COSV52709477; called by muse, mutect2, varscan2
- IL36RN | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61010512; called by muse, mutect2
- INTS8 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV58250162; called by muse, mutect2, varscan2
- IQSEC2 | c.1401G>T p.Q467H (on ENST00000642864 / NM_001111125.3; = p.Q262H on NM_015075.2) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64725231; called by muse, mutect2, varscan2
- IRGC | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as COSV54984025; called by muse, mutect2, varscan2
- ITPR3 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV65408635; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67347581; called by muse, mutect2, varscan2
- KALRN | c.1895G>C p.R632T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53762525; called by muse, mutect2, varscan2
- KCNH1 | c.1358C>A p.S453* (on ENST00000271751 / NM_172362.3; = p.S426* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | catalogued as COSV55080230; called by muse, mutect2, varscan2
- KCNT2 | c.2977C>A p.R993S | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as rs1440122635, COSV54077893, COSV99655816; called by muse, mutect2, varscan2
- KIAA1549 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs952569464, COSV54313258; called by muse, varscan2
- KLHL1 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV64771837; called by muse, mutect2, varscan2
- KLHL10 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53173140; called by muse, mutect2, varscan2
- KLK6 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59565519; called by muse, mutect2, varscan2
- KRT222 | c.121dup p.M41Nfs*5 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs748510701; called by mutect2, varscan2
- KRTAP27-1 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV67001192; called by muse, mutect2, varscan2
- LEPROT | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60753576; called by muse, mutect2, varscan2
- LRIG1 | c.1688A>C p.H563P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56239589; called by muse, mutect2, varscan2
- LRP12 | c.1985G>C p.R662T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV52628432, COSV52629437; called by muse, mutect2
- LRRC4C | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV53419333, COSV53424717; called by muse, mutect2, varscan2
- MAGI1 | c.4118C>T p.S1373F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1267352369, COSV58324869; called by muse, mutect2, varscan2
- MED12 | c.3281G>A p.G1094E | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61338954; called by muse, mutect2, varscan2
- MROH2B | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101270569, COSV68183631; called by muse, mutect2
- MSH4 | c.2428A>G p.M810V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs111548015, COSV54202202; called by muse, mutect2, varscan2
- MTHFD1L | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1259367690, COSV66209620; called by muse, mutect2, varscan2
- MUC17 | c.5062G>A p.G1688R | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748448650, COSV60287606; called by muse, varscan2
- MYO16 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs200506397, COSV51791810; called by muse, mutect2, varscan2
- MYO5C | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV55905723; called by muse, mutect2
- MYPN | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.327); catalogued as COSV62733625; called by muse, mutect2, varscan2
- NIPAL4 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs771029335, COSV61729897; called by muse, mutect2
- NOX3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV50151545; called by muse, mutect2, varscan2
- NR0B1 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66764053; called by muse, mutect2, varscan2
- NRDE2 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100583696; called by muse, mutect2
- NRXN3 | c.3119G>A p.G1040E (on ENST00000335750 / NM_001330195.2; = p.G667E on NM_004796.6) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59744148; called by muse, mutect2, varscan2
- OR10S1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.197); catalogued as COSV73342773; called by muse, mutect2, varscan2
- OR2T4 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV63543913; called by muse, mutect2, varscan2
- OR4N5 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as COSV61320496; called by muse, mutect2, varscan2
- OR5AC2 | c.509T>A p.F170Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62279416; called by muse, mutect2, varscan2
- OR5D16 | c.371A>T p.H124L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65721872; called by muse, mutect2, varscan2
- OR6X1 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100020680; called by muse, mutect2, varscan2
- OR8K1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV54402391; called by muse, mutect2, varscan2
- PARP4 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67961636; called by muse, mutect2, varscan2
- PCDH11X | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53462729; called by muse, mutect2
- PCDH19 | c.2833C>T p.Q945* (on ENST00000373034 / NM_001184880.2; = p.Q897* on NM_020766.3) | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV55262219, COSV55271735; called by muse, mutect2, varscan2
- PCDHGC5 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775132338, COSV52751007; called by muse, mutect2
- PEG3 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs369854592, COSV55632454; called by muse, mutect2, varscan2
- PHKA1 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV59805555; called by muse, mutect2
- PLCE1 | c.4585G>T p.D1529Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.61); catalogued as COSV99597656; called by muse, mutect2, varscan2
- PLK4 | c.773C>A p.S258* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as COSV54637331; called by muse, mutect2, varscan2
- PRPS2 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66126233; called by muse, mutect2
- PRR16 | c.488C>A p.P163H (on ENST00000407149 / NM_001300783.2; = p.P140H on NM_016644.2) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV65398871; called by muse, mutect2, varscan2
- RAB6B | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs1417399223, COSV53313382; called by muse, mutect2, varscan2
- RACGAP1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 127/189 reads (67%) | catalogued as COSV56699244; called by muse, mutect2, varscan2
- RAPGEF2 | c.3810G>C p.E1270D | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.012); catalogued as COSV52427513; called by muse, mutect2
- RNF148 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57361719; called by muse, mutect2, varscan2
- RSRC1 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55828026, COSV55840791; called by muse, mutect2, varscan2
- RXFP1 | c.985A>T p.N329Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57049572; called by muse, mutect2, varscan2
- SAP130 | c.3088C>A p.L1030I | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.689); catalogued as COSV99385459; called by muse, mutect2
- SCARB1 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.068); catalogued as rs779551591, COSV55547281; called by muse, mutect2
- SCN7A | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV69271215; called by muse, mutect2, varscan2
- SEC24A | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV59747119; called by muse, mutect2, varscan2
- SEC31B | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV64844305; called by muse, mutect2, varscan2
- SEMA3D | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV52392489; called by muse, mutect2
- SERPINA6 | c.661T>A p.F221I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58584785; called by muse, mutect2
- SERPINA9 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV54074570; called by muse, mutect2
- SEZ6L | c.1536G>C p.Q512H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as rs1479968430, COSV50663123; called by muse, mutect2, varscan2
- SGCZ | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101166525; called by muse, mutect2
- SHROOM2 | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV66606307; called by muse, mutect2
- SLC25A14 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 21/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV54417978; called by muse, mutect2, varscan2
- SLC36A4 | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58396054, COSV58396525; called by muse, mutect2, varscan2
- SLC39A12 | c.1352T>A p.L451* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV66197057, COSV66197822; called by muse, mutect2
- SLC9A7 | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 76/107 reads (71%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.935); catalogued as COSV60379878; called by muse, mutect2, varscan2
- SLITRK1 | c.2018G>T p.W673L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.12); catalogued as COSV65675417; called by muse, mutect2, varscan2
- SORL1 | c.4577C>T p.A1526V | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.135); catalogued as COSV52754032; called by muse, mutect2, varscan2
- SPATA18 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV54643607, COSV54644218, COSV54649193; called by muse, mutect2
- SRL | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV68423307; called by muse, mutect2
- STAG1 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV99367216; called by muse, mutect2, varscan2
- TAF7L | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100229680, COSV61256977; called by mutect2, varscan2
- TCF7 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.587); catalogued as COSV58656603; called by muse, mutect2
- TCP11L1 | c.1468A>G p.N490D | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57515189; called by muse, mutect2, varscan2
- TEC | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 49/243 reads (20%) | catalogued as COSV67404692; called by muse, mutect2, varscan2
- THOC2 | c.4666G>T p.G1556C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as rs769593183, COSV99834395; called by muse, mutect2, varscan2
- THOC2 | c.3392T>A p.L1131H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55545336; called by muse, mutect2
- TMEM64 | c.951G>A p.Q317= | Splice Region (SNP) | VAF 8/103 reads (8%) | catalogued as COSV69127770; called by muse, mutect2
- TOPORS | c.1923A>T p.R641S | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); catalogued as COSV62116816; called by muse, mutect2, varscan2
- TSPYL2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs782227977, COSV60233767, COSV60237261; called by muse, mutect2
- TTC7B | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.84); catalogued as COSV60630414; called by muse, mutect2
- UBL5 | c.57-1G>A p.X19_splice | Splice Site (SNP) | VAF 38/153 reads (25%) | catalogued as COSV62339852; called by muse, mutect2, varscan2
- USH2A | c.14161G>T p.A4721S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV56364557; called by muse, mutect2, varscan2
- YARS2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1205614378, COSV61401773; called by muse, mutect2
- ZDHHC14 | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58194256, COSV58195975; called by muse, mutect2, varscan2
- ZFHX4 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50483022, COSV50754686, COSV51443398; called by muse, mutect2, varscan2
- ZNF3 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52795766, COSV52796069; called by muse, mutect2
- ZNF518A | c.2440G>T p.D814Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV100283781; called by muse, mutect2
- ZNF560 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV56867641; called by muse, mutect2
- ZNF780A | c.1794G>A p.M598I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100575285; called by muse, mutect2, varscan2
- CAV2 | c.390_395dup p.T131_I132insMT | In Frame Ins (INS) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- IGHA2 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MRC1 | c.2192G>T p.G731V | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.3053del p.G1018Afs*19 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- RFX5 | c.619del p.L207* | Frame Shift Del (DEL) | VAF 16/177 reads (9%) | called by mutect2, pindel
- WDTC1 | c.1973dup p.A659Cfs*5 (on ENST00000319394 / NM_001276252.2; = p.A658Cfs*5 on NM_015023.5) | Frame Shift Ins (INS) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- ABCA3 | c.159C>T p.N53= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs191085051, COSV57049259, COSV57053114; called by muse, mutect2, varscan2
- ACSS3 | c.1437C>A p.V479= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99699582; called by muse, mutect2
- ADCY8 | c.1536C>T p.S512= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs150100724; called by muse, mutect2, varscan2
- ATP7A | c.2286G>A p.L762= | Silent (SNP) | VAF 26/371 reads (7%) | catalogued as COSV58445841; called by muse, mutect2
- ATRX | c.4737G>T p.V1579= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV64876103; called by muse, mutect2, varscan2
- CACNB3 | c.1272C>T p.H424= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1195918171, COSV56398184; called by muse, mutect2, varscan2
- CDH19 | c.2025C>T p.S675= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV50958278; called by muse, mutect2, varscan2
- CES5A | c.1698C>A p.L566= (on ENST00000290567 / NM_001143685.2; = p.L516= on NM_145024.3) | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs370527653; called by muse, mutect2
- CNTNAP2 | c.1479C>T p.G493= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs779384498, COSV62175885; called by muse, mutect2, varscan2
- CORO2B | c.582G>T p.L194= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55952661; called by muse, mutect2, varscan2
- DCAF4 | c.831C>T p.L277= | Silent (SNP) | VAF 49/373 reads (13%) | catalogued as COSV62319522; called by muse, mutect2, varscan2
- DOCK2 | c.141A>T p.G47= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV56956401; called by muse, mutect2
- DOCK2 | c.3567G>T p.R1189= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV56956412; called by muse, mutect2, varscan2
- DTX3L | c.1971A>G p.G657= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV56144075; called by muse, varscan2
- EHBP1L1 | c.1188A>G p.P396= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58572815; called by muse, mutect2, varscan2
- EPB42 | c.1848C>A p.A616= (on ENST00000441366 / NM_001114134.2; = p.A646= on NM_000119.3) | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV55749527; called by muse, mutect2, varscan2
- EPX | c.750C>T p.G250= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs943769778, COSV56596111; called by muse, mutect2
- ERAL1 | c.87G>A p.R29= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs770674816, COSV54739838; called by muse, mutect2, varscan2
- FAT2 | c.615G>A p.V205= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV55819071; called by muse, mutect2
- GLP1R | c.1305C>G p.P435= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as COSV64714871; called by muse, mutect2
- GPM6A | c.126G>T p.L42= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as COSV54541085; called by muse, mutect2
- HCN1 | c.1908C>T p.I636= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as COSV57492543, COSV57537064; called by muse, mutect2, varscan2
- HMGN5 | c.30T>G p.G10= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV63916920; called by muse, mutect2
- INSRR | c.2160G>A p.A720= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV63872859; called by muse, mutect2, varscan2
- JMJD6 | c.540A>G p.P180= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV57972158; called by muse, mutect2, varscan2
- KCND2 | c.375C>A p.I125= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV58578437; called by muse, mutect2, varscan2
- LEPR | c.546G>A p.Q182= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV60753585; called by muse, mutect2, varscan2
- LINGO1 | c.90G>A p.V30= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV62436917; called by muse, mutect2
- LPCAT2 | c.786A>G p.Q262= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV50895377; called by muse, mutect2
- MAT1A | c.21C>A p.G7= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV64745456; called by muse, mutect2, varscan2
- MFAP5 | c.24G>C p.V8= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1279885534, COSV63945310; called by muse, mutect2, varscan2
- MFSD1 | c.633C>T p.L211= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs147447476; called by muse, mutect2, varscan2
- MMP2 | c.102C>T p.I34= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV54601008; called by muse, mutect2
- MYH11 | c.3009C>A p.L1003= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV55552062, COSV55562990; called by muse, mutect2, varscan2
- NMUR2 | c.459C>T p.R153= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1004624182, COSV99677400; called by muse, mutect2, varscan2
- NOX3 | c.183G>A p.L61= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV50151502; called by muse, mutect2, varscan2
- OR13C2 | c.21C>A p.T7= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV73377700, COSV73377717; called by muse, mutect2, varscan2
- OR1J4 | c.585T>C p.N195= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV61589779; called by muse, mutect2, varscan2
- OR52D1 | c.924A>G p.L308= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV59487468; called by muse, mutect2, varscan2
- OR6X1 | c.867T>A p.T289= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100020681; called by muse, mutect2, varscan2
- PCDHA6 | c.552A>T p.I184= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV65352042, COSV65352896; called by muse, mutect2
- PCDHB9 | c.2001C>T p.S667= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs1432422630, COSV53378342; called by muse, mutect2, varscan2
- PDZD2 | c.4842T>C p.P1614= | Silent (SNP) | VAF 78/341 reads (23%) | catalogued as COSV56857402; called by muse, mutect2, varscan2
- POF1B | c.594C>A p.V198= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV99427598; called by muse, mutect2
- PRAMEF4 | c.684A>G p.P228= | Silent (SNP) | VAF 59/343 reads (17%) | catalogued as COSV52438534; called by muse, mutect2, varscan2
- PRDM9 | c.330G>T p.V110= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as COSV99691458; called by muse, mutect2
- PSAT1 | c.988T>C p.L330= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV61302332, COSV61302610; called by muse, mutect2, varscan2
- PTF1A | c.927C>G p.L309= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV64735034, COSV64735309; called by muse, mutect2
- PTPRO | c.3417C>A p.G1139= (on ENST00000281171 / NM_030667.3; = p.G1111= on NM_002848.4) | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as rs370164792, COSV55509569; called by muse, mutect2, varscan2
- PUS3 | c.492C>G p.L164= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV57102971; called by muse, mutect2
- RD3 | c.87T>C p.L29= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as rs1188420700, COSV65362258; called by muse, mutect2, varscan2
- RELN | c.8928G>T p.L2976= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as COSV59000054; called by muse, mutect2
- SLC34A3 | c.51G>A p.A17= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs528614270, COSV63186667; called by muse, mutect2, varscan2
- SYNPO2 | c.168C>T p.I56= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV61110302; called by muse, mutect2
- TENM1 | c.5790G>T p.V1930= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV64431152; called by muse, mutect2, varscan2
- TRIP12 | c.5244A>G p.S1748= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV52263341; called by muse, mutect2, varscan2
- UNC79 | c.6006G>T p.T2002= (on ENST00000393151 / NM_001346218.2; = p.T1825= on NM_020818.5) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99830143; called by muse, mutect2
- UTS2B | c.252A>G p.L84= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV61278471; called by muse, mutect2, varscan2
- VAMP7 | c.195C>T p.I65= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV52901704; called by muse, mutect2, varscan2
- ZFAND2A | c.159C>T p.H53= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs779045778, COSV57180252; called by muse, mutect2, varscan2
- ZNF18 | c.216A>G p.P72= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1462893669, COSV59551218; called by muse, mutect2, varscan2
- ZSCAN22 | c.1179G>A p.T393= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs530965276, COSV61639072; called by muse, mutect2, varscan2
- AC024940.1 | n.2404C>T | RNA (SNP) | VAF 6/52 reads (12%) | catalogued as rs745981038; called by mutect2, varscan2
- AL353804.6 | chrX:73826602 A>T | 3'Flank (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1129G>T | RNA (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1593G>T | RNA (SNP) | VAF 30/117 reads (26%) | called by muse, mutect2, varscan2
- C10orf95 | c.-20A>T | 5'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53309268; called by muse, mutect2
- C8orf31 | n.388A>G | RNA (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- FBXL21P | n.1057T>A | RNA (SNP) | VAF 15/105 reads (14%) | catalogued as COSV51808967; called by muse, mutect2, varscan2
- HECTD1 | c.*1G>A | 3'UTR (SNP) | VAF 7/56 reads (13%) | catalogued as COSV101237556; called by muse, mutect2, varscan2
